Gene-level copy-number profile of tumor specimen HCM-BROD-0423-C71-01A from HCMI case HCM-BROD-0423-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 37.9 years (13,854 days).
Specimen HCM-BROD-0423-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff098cd1-0fe6-4eb5-86de-80a3addce6fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0423-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/294280a6-78f8-42c5-928a-4098eaca671c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 11; copy number 2: 6,134; copy number 3: 21; copy number 4: 40,814; copy number 5: 187; copy number 6: 11,721; copy number 7: 1; copy number 8: 7; copy number 67: 4; copy number 128: 2; copy number 144: 1; copy number 146: 4; copy number 231: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,890,482, 2 genes: AL645929.1, HLA-H.
- chr6:29,906,543–29,934,286, 5 genes: DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:50,866,747–51,022,990, 2 genes, copy number 128 (within-gene range 4–130): AC004830.2, AC004830.1.
- chr7:54,752,250–55,433,742, 10 genes, copy number 67–231: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
